Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54D, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54D-01A (Primary Tumor).

[page 1 of 4]
ICDO-3

Carcinoma, renal cell, NOS
Clear Cell type 8312/3

Site:

② Kidney^{NOS} C64.9

11/30/12 JVO

Diagnosis:

A: Kidney, left, left hand assisted laparoscopic nephrectomy

Histologic tumor type/subtype: renal cell carcinoma,
conventional clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2 (of 4)

Tumor size (greatest dimension): 12.9 cm maximum tumor size by
gross examination

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: focal microscopic
capsular

invasion identified

Gerota' s fascia: negative

Renal sinus: negative

Major veins (renal vein or segmental branches, IVC): positive
for renal

vein invasion, macroscopic

Ureter: negative

Venous (large vessel): present, macroscopic

Lymphatic (small vessel): negative

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): not
applicable

Renal capsular margin (partial nephrectomy only): not applicable

Paranephric adipose tissue margin (partial nephrectomy only):
not

applicable

Gerota' s fascia (nephrectomy): negative

Renal vein (nephrectomy): negative

Ureter (nephrectomy): negative

Adrenal gland: benign adrenal tissue with no tumor seen

[page 2 of 4]
Lymph nodes: none identified

Other significant findings: none

AJCC Staging: pT3a pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

B: Adrenal, adrenalectomy

- Adrenal gland with no tumor seen.

C: Soft tissue, abdominal wall fat, removal

- Fibroadipose, fibrovascular and fibrous soft tissue with no tumor seen.

Clinical History:

year-old male with renal mass.

Gross Description:

Received are three appropriately labeled containers.

Specimen A is labeled "left kidney" and holds a 760 gram (perinephric fat removed), 25 x 17 x 7 cm kidney. Adherent to the superior aspect is a portion of the adrenal gland approximately 3.0 x 1.0 x 0.2 cm. The attached segment of ureter is 3.2 cm in length x 0.2 cm in diameter and patent. The renal vein is 1.3 cm in diameter and filled with yellow/brown tumor thrombus. The renal artery is 0.4 cm in diameter and patent. The capsule is intact, tan, smooth and nodular. On section, >80% of the parenchymal has been replaced by a 12.9 x 8.4 x 7.9 cm red/brown to orange/yellow soft, cystic, variegated, well-circumscribed mass. With the center of the mass, there is a white, firm, fibrous area.

[page 3 of 4]
approximately 3.5 cm. The mass pushes but does not invade through the capsule grossly, abuts but does not grossly appear to invade into the attached portion of adrenal gland, invades into but is not present at the renal vein margin, abuts but does not grossly appear to invade into the renal sinus, and is >3 cm from the ureteral margin. No additional abnormalities are noted. No enlarged palpable lymph node candidates are present at the hilum. The uninvolved cortical parenchyma is tan/brown with a distinct corticomedullary junction.

Block Summary:

- A1 - Ureteral vein and artery margins, en face
- A2 - Section of renal vein, cross section to include sinus fat and other sinus structure
- A3 - Mass with respect to adrenal gland
- A4-A5 - Mass with respect to capsule
- A6-A7 - Mass and adjacent renal parenchyma
- A8 - Mass and adjacent renal parenchyma and pelvis
- A9 - Uninvolved renal parenchyma away from mass

Tumor and normal are submitted to tissue procurement.

Container B is additionally labeled "adrenal gland" and holds a 12.7 gram, 8.7 x 1.9 x 0.4 cm adrenal gland with attached adipose tissue. The adrenal gland is serially sectioned to reveal a golden orange/yellow cortical rim approximately 0.4 cm thick and a tan/brown <0.1 mm thick medulla. The adrenal vein is identified, 0.2 cm in diameter, and patent. Three representative sections are submitted in B1-B3 with the remaining tissue retained in formalin.

Container C is additionally labeled "abdominal wall fat" and holds a 6.5 x 5.5 x 3.0 cm fragment of dark tan/brown smooth lobulated fat. On section, the cut surface is notable for a tan/pink tubular structure along the edge, 1.5 cm in

[page 4 of 4]
length. No additional abnormalities are noted. The tubular structure and adjacent adipose tissue is submitted in C1-C2. Additional sections of fat are submitted in C3. The remaining tissue is retained in formalin.

Metastatic Discrepancy		☒

W 12/4/12

9/29/12

Source: NCI Genomic Data Commons file 57ab7b70-dbe6-4067-a930-c1ac0ea22ba8 (TCGA-B8-A54D.79A96E1A-59A4-4EA6-82E0-4D018BF4E3B8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).